Somatic mutation profile of tumor specimen 0DBQFH from CCDI case PBBLEJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.3 years (465 days).
Specimen 0DBQFH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b4b5c99-bafe-4e42-8a45-c0a790e01999.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBQF7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a56c3c7-fbaf-493d-9ab8-68c75b3e307e

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CROCC | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 74/834 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776568599; called by muse, mutect2
- LCT | c.4762G>A p.A1588T | Missense Mutation (SNP) | VAF 68/632 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as rs374357262; called by muse, mutect2, varscan2
- OR10R2 | c.482G>T p.C161F | Missense Mutation (SNP) | VAF 32/624 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1414239581, COSV63769288; called by muse, mutect2
- AP3D1 | c.1214G>C p.S405T | Missense Mutation (SNP) | VAF 33/811 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 19/644 reads (3%) | called by muse, mutect2
- HMCN2 | c.563C>A p.T188N | Missense Mutation (SNP) | VAF 23/636 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); called by muse, mutect2
- WNK1 | c.1502A>T p.K501I | Missense Mutation (SNP) | VAF 28/930 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 42/964 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- BPI | c.-41G>A | 5'UTR (SNP) | VAF 18/400 reads (5%) | called by muse, mutect2
